Somatic mutation profile of tumor specimen HCM-BROD-0234-C49-06A (aliquot HCM-BROD-0234-C49-06A-11D-A80U-36) from HCMI case HCM-BROD-0234-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Spindle cell sarcoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 76.5 years (27,950 days).
Specimen HCM-BROD-0234-C49-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d900cf9d-22ca-40ad-858b-92e928ca54f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0234-C49-10B (Blood Derived Normal), aliquot HCM-BROD-0234-C49-10B-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c13656af-ea1f-41ae-b6ad-8d81830b1fe7

The open-access MAF lists 880 somatic variants for this specimen: 542 protein-altering or splice-affecting, 302 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 495, Silent 302, Nonsense Mutation 23, Intron 23, Splice Region 8, Frame Shift Del 7, 5'Flank 6, Splice Site 6, Frame Shift Ins 3, 3'UTR 3, RNA 2, 5'UTR 1.

Variants (750 of 880; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 284/337 reads (84%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RAC1 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 225/348 reads (65%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as rs1057519948, COSV61821585, COSV61824963; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AAAS | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 296/407 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52932091; called by muse, mutect2, varscan2
- ABCB9 | c.849G>A p.G283= | Splice Region (SNP) | VAF 129/188 reads (69%) | catalogued as rs1190968092; called by muse, mutect2, varscan2
- ABCC3 | c.4072G>A p.G1358S | Missense Mutation (SNP) | VAF 201/406 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs187814086, COSV53323190; called by muse, mutect2, varscan2
- AC119396.1 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 86/169 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.712); catalogued as rs574718933; called by muse, mutect2, varscan2
- ACOD1 | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 57/243 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.599); catalogued as rs763833075; called by muse, mutect2, varscan2
- ACOD1 | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 58/241 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs538660196; called by muse, mutect2, varscan2
- ACOT9 | c.923A>G p.N308S | Missense Mutation (SNP) | VAF 148/169 reads (88%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs748728551; called by muse, mutect2, varscan2
- ACTN3 | c.637-1G>A p.X213_splice | Splice Site (SNP) | VAF 166/338 reads (49%) | catalogued as COSV72207668; called by muse, mutect2, varscan2
- ADAMTS20 | c.899G>A p.G300E | Missense Mutation (SNP) | VAF 27/242 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV67126043; called by muse, mutect2, varscan2
- ADAR | c.490A>C p.K164Q | Missense Mutation (SNP) | VAF 217/432 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.265); catalogued as COSV52712412; called by muse, mutect2, varscan2
- ADCY5 | c.1874G>A p.G625E | Missense Mutation (SNP) | VAF 71/342 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59201376; called by muse, mutect2, varscan2
- ADGRF5 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 31/247 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs1373208554; called by muse, mutect2, varscan2
- ADGRL2 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54655701; called by muse, mutect2, varscan2
- AFF2 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 225/251 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs782804418; called by muse, mutect2, varscan2
- ALOX5 | c.2006C>T p.P669L | Missense Mutation (SNP) | VAF 232/551 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs777199179, COSV65553342; called by muse, mutect2, varscan2
- ANKFN1 | c.1215G>A p.R405= | Splice Region (SNP) | VAF 121/227 reads (53%) | catalogued as rs747822420; called by muse, mutect2, varscan2
- ANKRD12 | c.5194C>T p.P1732S | Missense Mutation (SNP) | VAF 159/217 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as rs1014443518, COSV100040913, COSV50819304; called by muse, mutect2, varscan2
- ANKRD16 | c.657C>A p.D219E | Missense Mutation (SNP) | VAF 144/294 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.299); catalogued as COSV51948652; called by muse, mutect2, varscan2
- APBB1IP | c.1823C>T p.P608L | Missense Mutation (SNP) | VAF 171/358 reads (48%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs1029796857; called by muse, mutect2, varscan2
- ARHGAP21 | c.2774C>T p.S925F | Missense Mutation (SNP) | VAF 184/451 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1265976883; called by muse, mutect2, varscan2
- ARHGEF5 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 185/843 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV99282861, COSV99283215; called by muse, mutect2, varscan2
- ASXL1 | c.2309C>T p.S770L | Missense Mutation (SNP) | VAF 246/425 reads (58%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); catalogued as COSV60103934, COSV60119071; called by muse, mutect2, varscan2
- ATP1B2 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 232/448 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.187); catalogued as rs752825639; called by muse, mutect2
- ATP2A1 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 260/361 reads (72%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as rs937724681, COSV63921399; called by muse, varscan2
- ATP8B2 | c.2251G>A p.E751K (on ENST00000672630; = p.E718K on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/284 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as COSV59246841; called by muse, mutect2, varscan2
- BCORL1 | c.3601G>A p.E1201K | Missense Mutation (SNP) | VAF 224/254 reads (88%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs372174837; called by muse, mutect2, varscan2
- BMP1 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 60/316 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1398538193; called by muse, varscan2
- BRCA1 | c.3943C>T p.P1315S | Missense Mutation (SNP) | VAF 209/506 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.046); catalogued as COSV58803516; called by muse, mutect2, varscan2
- C6orf15 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 110/645 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1454509351; called by muse, mutect2, varscan2
- C7 | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 148/258 reads (57%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV57471726; called by muse, mutect2, varscan2
- CAPN3 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 327/466 reads (70%) | SIFT tolerated (0.22); PolyPhen benign (0.261); catalogued as rs756192789, COSV58820671; called by muse, mutect2, varscan2
- CARD11 | c.2270G>A p.G757E | Missense Mutation (SNP) | VAF 103/394 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs568928567, COSV99052457; called by muse, mutect2, varscan2
- CC2D1B | c.919C>T p.R307* | Nonsense Mutation (SNP) | VAF 244/272 reads (90%) | catalogued as rs773525251; called by muse, varscan2
- CCDC141 | c.2983G>A p.D995N | Missense Mutation (SNP) | VAF 310/416 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs752646500; called by muse, mutect2, varscan2
- CCL1 | c.77T>G p.M26R | Missense Mutation (SNP) | VAF 105/215 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs765973747; called by muse, mutect2, varscan2
- CDH23 | c.8726G>A p.S2909N | Missense Mutation (SNP) | VAF 47/251 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs397517361; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDKN2AIP | c.1347G>T p.W449C | Missense Mutation (SNP) | VAF 73/542 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100187658; called by muse, mutect2, varscan2
- CEACAM7 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 73/123 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV50073185; called by muse, mutect2, varscan2
- CES3 | c.1240G>A p.G414S | Missense Mutation (SNP) | VAF 315/352 reads (89%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.458); catalogued as rs763155745; called by muse, mutect2, varscan2
- CHGB | c.1432G>A p.G478R | Missense Mutation (SNP) | VAF 118/201 reads (59%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs774344332; called by muse, mutect2, varscan2
- CHST9 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV52429078; called by muse, mutect2, varscan2
- CLCN7 | c.1667T>G p.L556R | Missense Mutation (SNP) | VAF 353/508 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99247716; called by muse, mutect2, varscan2
- CNTN5 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 135/249 reads (54%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.948); catalogued as COSV54281336, COSV54342027; called by muse, mutect2, varscan2
- COL11A1 | c.3008G>A p.G1003E | Missense Mutation (SNP) | VAF 288/318 reads (91%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62173003; called by muse, mutect2, varscan2
- COL9A1 | c.1582C>T p.P528S | Missense Mutation (SNP) | VAF 157/242 reads (65%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.472); catalogued as COSV57886010; called by muse, mutect2, varscan2
- CPLANE1 | c.8668G>T p.D2890Y | Missense Mutation (SNP) | VAF 108/355 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV57059989, COSV99950331; called by muse, mutect2, varscan2
- CRB2 | c.859G>A p.G287S | Missense Mutation (SNP) | VAF 120/738 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.202); catalogued as COSV63503667; called by muse, mutect2, varscan2
- CRB2 | c.860G>A p.G287D | Missense Mutation (SNP) | VAF 123/742 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as rs1442571958, COSV63505898; called by muse, mutect2, varscan2
- CRISPLD1 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 146/262 reads (56%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as rs1321970308; called by muse, mutect2, varscan2
- CROCC | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 231/280 reads (83%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV65015070; called by muse, mutect2, varscan2
- CSMD1 | c.8944C>T p.P2982S (on ENST00000520002; = p.P2981S on NM_033225.6) | Missense Mutation (SNP) | VAF 143/222 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59326145; called by muse, mutect2, varscan2
- CSN2 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 243/280 reads (87%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs980267132, COSV100778821, COSV61992322; called by muse, mutect2, varscan2
- CTR9 | c.2665C>T p.L889F | Missense Mutation (SNP) | VAF 121/302 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63728426; called by muse, mutect2, varscan2
- CUL7 | c.2492C>T p.S831F | Missense Mutation (SNP) | VAF 285/425 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs369629454; called by muse, mutect2, varscan2
- CUL9 | c.7318G>A p.E2440K | Missense Mutation (SNP) | VAF 196/296 reads (66%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs756475860; called by muse, mutect2, varscan2
- CXXC5 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 99/336 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs762307804, COSV100210835; called by muse, mutect2, varscan2
- CYP11A1 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 68/409 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs999606408; called by muse, mutect2, varscan2
- CYP2A6 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 71/352 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.105); catalogued as COSV104397077; called by muse, mutect2, varscan2
- CYP2C8 | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 184/291 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs772497816; called by muse, mutect2, varscan2
- CYP2C9 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 263/308 reads (85%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as COSV53246817; called by muse, mutect2, varscan2
- DACT1 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 65/495 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.368); catalogued as rs780349654; called by muse, mutect2, varscan2
- DAOA | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV61601631; called by muse, mutect2, varscan2
- DCC | c.4186C>T p.P1396S | Missense Mutation (SNP) | VAF 65/336 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV71431528; called by muse, mutect2, varscan2
- DEUP1 | c.1648G>A p.D550N | Missense Mutation (SNP) | VAF 102/211 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.372); catalogued as COSV99977049, COSV99977511; called by muse, mutect2, varscan2
- DHX30 | c.2863C>T p.R955C (on ENST00000445061 / NM_138615.3; = p.R916C on NM_014966.3) | Missense Mutation (SNP) | VAF 169/504 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.744); catalogued as rs766335935; called by muse, mutect2, varscan2
- DIAPH2 | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 147/162 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100235878; called by muse, mutect2, varscan2
- DIAPH3 | c.3499G>A p.E1167K | Missense Mutation (SNP) | VAF 183/305 reads (60%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); catalogued as rs775688879; called by muse, mutect2, varscan2
- DNAH6 | c.6629C>T p.S2210L | Missense Mutation (SNP) | VAF 132/350 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs1365729676, COSV52851796; called by muse, mutect2, varscan2
- DOCK1 | c.4455G>A p.V1485= | Splice Region (SNP) | VAF 126/199 reads (63%) | catalogued as rs370127033; called by muse, mutect2, varscan2
- DRD5 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 365/483 reads (76%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.675); catalogued as rs773943990, COSV58578778; called by muse, mutect2, varscan2
- DSG1 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 46/279 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57133137; called by muse, mutect2, varscan2
- DUSP8 | c.421C>G p.P141A | Missense Mutation (SNP) | VAF 263/567 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV100524517; called by muse, mutect2, varscan2
- DYRK3 | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 94/479 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs202021957; called by muse, mutect2
- ERICH3 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 199/215 reads (93%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs267598719; called by muse, mutect2, varscan2
- FIGNL1 | c.1666C>T p.R556W | Missense Mutation (SNP) | VAF 258/410 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780152080; called by muse, mutect2, varscan2
- FILIP1 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 88/343 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV52726507; called by muse, mutect2, varscan2
- FIS1 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 291/454 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99778907; called by muse, mutect2, varscan2
- FLRT3 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 82/287 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777359374, COSV54039664; called by muse, mutect2, varscan2
- FRMD7 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 254/280 reads (91%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs750688292; called by muse, mutect2, varscan2
- GABBR1 | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 71/426 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63541692; called by muse, mutect2, varscan2
- GABRB1 | c.367T>A p.F123I | Missense Mutation (SNP) | VAF 116/368 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99783881; called by muse, varscan2
- GADL1 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 166/336 reads (49%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.537); catalogued as rs1409667154, COSV56985756; called by muse, mutect2, varscan2
- GLP1R | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 50/378 reads (13%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.017); catalogued as rs1156801898; called by mutect2, varscan2
- GLT1D1 | c.310C>T p.L104F | Missense Mutation (SNP) | VAF 42/252 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as rs781124799, COSV55882678; called by muse, mutect2, varscan2
- GLT1D1 | c.931G>A p.E311K (on ENST00000442111 / NM_001366889.1; = p.E231K on NM_144669.3) | Missense Mutation (SNP) | VAF 207/293 reads (71%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV55882961; called by muse, mutect2, varscan2
- GOLGA3 | c.2057G>A p.R686K | Missense Mutation (SNP) | VAF 413/476 reads (87%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52645192; called by muse, mutect2, varscan2
- GOLGA6A | c.1609C>T p.L537F | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs1361700046; called by mutect2, varscan2
- GOLGA6B | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as rs1304327858; called by mutect2, varscan2
- GPX2 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 74/555 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs200618749; called by muse, mutect2, varscan2
- GRK7 | c.115C>A p.L39M | Missense Mutation (SNP) | VAF 321/508 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747391734, COSV99379754, COSV99380173; called by muse, mutect2, varscan2
- GRN | c.1489A>G p.K497E | Missense Mutation (SNP) | VAF 197/544 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs952213951; called by muse, mutect2, varscan2
- H1-7 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 86/604 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV58601915; called by muse, mutect2, varscan2
- H1-8 | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 222/349 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as rs752419831; called by muse, mutect2, varscan2
- HEATR1 | c.2789C>T p.P930L | Missense Mutation (SNP) | VAF 94/284 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as rs1294243318; called by muse, mutect2, varscan2
- HEATR5B | c.4691C>T p.S1564F | Missense Mutation (SNP) | VAF 231/427 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as rs893846419; called by muse, mutect2, varscan2
- HEPACAM2 | c.467C>T p.P156L (on ENST00000394468 / NM_001039372.4; = p.P144L on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 233/367 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs865778058; called by muse, mutect2, varscan2
- HNMT | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 179/288 reads (62%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.976); catalogued as COSV54511022; called by muse, mutect2, varscan2
- HS3ST4 | c.1363G>A p.D455N | Missense Mutation (SNP) | VAF 40/254 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); catalogued as COSV58806132; called by muse, mutect2, varscan2
- HSCB | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 329/713 reads (46%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs932257117; called by muse, mutect2, varscan2
- HSPA12A | c.1351C>A p.L451I | Missense Mutation (SNP) | VAF 64/298 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV65021712; called by muse, mutect2, varscan2
- HTR2A | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 137/254 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.444); catalogued as COSV66326570; called by muse, mutect2, varscan2
- HTR4 | c.328C>T p.H110Y | Missense Mutation (SNP) | VAF 72/221 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867725219, COSV58789896; called by muse, mutect2, varscan2
- IFT88 | c.433G>A p.E145K (on ENST00000319980 / NM_001318493.2; = p.E136K on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.411); catalogued as rs764712905, COSV60673703; called by muse, mutect2, varscan2
- IGF2BP3 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 234/400 reads (59%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.846); catalogued as rs764971109, COSV51679803; called by muse, mutect2, varscan2
- IGHV1-18 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 335/996 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as rs373213848; called by muse, varscan2
- INTU | c.817C>T p.H273Y | Missense Mutation (SNP) | VAF 255/394 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1176904927; called by muse, mutect2, varscan2
- IRF2BP2 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 389/763 reads (51%) | catalogued as COSV100784403; called by muse, mutect2, varscan2
- ITPR1 | c.7963G>A p.E2655K (on ENST00000354582; = p.E2600K on NM_002222.7) | Missense Mutation (SNP) | VAF 181/368 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV56978849; called by muse, mutect2, varscan2
- JUND | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 271/479 reads (57%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.791); catalogued as rs980876053; called by muse, mutect2, varscan2
- KCNH8 | c.3227G>A p.G1076E | Missense Mutation (SNP) | VAF 279/494 reads (56%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.027); catalogued as rs866087313, COSV60473823; called by muse, mutect2, varscan2
- KCNJ3 | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 221/340 reads (65%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.038); catalogued as COSV54534242; called by muse, mutect2, varscan2
- KCNT1 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 164/681 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as rs778405770, COSV53681862; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCTD5 | c.675G>A p.K225= | Splice Region (SNP) | VAF 254/339 reads (75%) | catalogued as rs1250492026; called by muse, mutect2, varscan2
- KDM4C | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 119/143 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as rs750594288; called by muse, mutect2, varscan2
- KDM4F | c.1630C>T p.P544S | Missense Mutation (SNP) | VAF 125/331 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs782056487; called by muse, mutect2, varscan2
- KIF21A | c.2305del p.T769Qfs*5 (on ENST00000361418 / NM_001378440.1; = p.T756Qfs*5 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 21/181 reads (12%) | catalogued as rs1219032396; called by mutect2, pindel, varscan2
- KIF26B | c.5957C>T p.P1986L | Missense Mutation (SNP) | VAF 292/576 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV63650950; called by muse, mutect2, varscan2
- KLHL4 | c.2152C>T p.P718S | Missense Mutation (SNP) | VAF 149/173 reads (86%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as COSV64144326; called by muse, mutect2, varscan2
- KMT5B | c.1655C>T p.S552F | Missense Mutation (SNP) | VAF 237/461 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV58564431; called by muse, mutect2, varscan2
- KRTAP19-3 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 195/730 reads (27%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.013); catalogued as rs770911384, COSV100477476, COSV61855299; called by muse, mutect2, varscan2
- KRTAP24-1 | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 233/359 reads (65%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.574); catalogued as rs774083954, COSV61088971; called by muse, mutect2, varscan2
- LDLR | c.2549G>A p.R850K | Missense Mutation (SNP) | VAF 143/290 reads (49%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.676); catalogued as rs879255228, CM067688; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRFN5 | c.1328G>A p.G443E | Missense Mutation (SNP) | VAF 140/238 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs760158675; called by muse, mutect2, varscan2
- LRRIQ4 | c.1375C>A p.L459I | Missense Mutation (SNP) | VAF 67/245 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as rs1002946974; called by muse, mutect2, varscan2
- MCCC1 | c.1394C>T p.T465I | Missense Mutation (SNP) | VAF 124/193 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1000891879; called by muse, mutect2, varscan2
- MCUR1 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 46/318 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.039); catalogued as COSV63958017; called by muse, varscan2
- ME3 | c.1282G>A p.D428N | Missense Mutation (SNP) | VAF 232/418 reads (56%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as rs770032541; called by muse, mutect2, varscan2
- MED16 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 111/220 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs969601088; called by muse, mutect2, varscan2
- MERTK | c.944G>A p.R315K | Missense Mutation (SNP) | VAF 151/237 reads (64%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs886871857; called by muse, mutect2, varscan2
- MMP14 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 76/382 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1456467056; called by muse, mutect2, varscan2
- MMP16 | c.1530C>G p.F510L | Missense Mutation (SNP) | VAF 178/259 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54194898; called by muse, varscan2
- MMS22L | c.1787C>T p.S596L | Missense Mutation (SNP) | VAF 179/275 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); catalogued as rs866715074, COSV51517224; called by muse, mutect2, varscan2
- MPPED2 | c.600G>A p.W200* | Nonsense Mutation (SNP) | VAF 948/1063 reads (89%) | catalogued as COSV63901781; called by muse, mutect2, varscan2
- MROH2B | c.2800C>A p.L934I | Missense Mutation (SNP) | VAF 40/398 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs1448281063; called by muse, mutect2
- MTHFD2 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 148/503 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1481756808; called by muse, mutect2, varscan2
- MUC12 | c.12187G>A p.E4063K (on ENST00000379442; = p.E3920K on NM_001164462.1) | Missense Mutation (SNP) | VAF 123/1291 reads (10%) | SIFT tolerated (0.12); catalogued as rs750395168; called by muse, mutect2, varscan2
- MUC16 | c.6578C>T p.S2193F | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV67462513; called by muse, mutect2, varscan2
- MUC22 | c.1882G>A p.A628T | Missense Mutation (SNP) | VAF 538/790 reads (68%) | SIFT tolerated (0.36); catalogued as rs567001093; called by muse, mutect2, varscan2
- MYH4 | c.4197G>C p.Q1399H | Missense Mutation (SNP) | VAF 32/408 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.852); catalogued as rs147966650; called by muse, mutect2
- MYLK2 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 168/506 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV101044917; called by muse, mutect2, varscan2
- MYO16 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.198); catalogued as rs201258873; called by muse, varscan2
- MYT1L | c.2276G>A p.R759Q | Missense Mutation (SNP) | VAF 286/499 reads (57%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs1384454881, COSV67719715; called by muse, mutect2, varscan2
- NAA60 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 276/402 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1567396028, COSV62655823; called by muse, mutect2, varscan2
- NBEA | c.8480G>A p.R2827H | Missense Mutation (SNP) | VAF 60/236 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.101); catalogued as rs376983676; called by muse, mutect2, varscan2
- NCOR2 | c.3200C>T p.P1067L | Missense Mutation (SNP) | VAF 375/555 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775451734; called by muse, mutect2, varscan2
- NEO1 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 67/481 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV56069672; called by muse, mutect2, varscan2
- NES | c.2497G>A p.G833R | Missense Mutation (SNP) | VAF 148/455 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV63961181; called by muse, varscan2
- NOTCH2 | c.6058G>A p.E2020K | Missense Mutation (SNP) | VAF 192/214 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56702339; called by muse, mutect2, varscan2
- NOTUM | c.1217C>T p.S406L | Missense Mutation (SNP) | VAF 363/730 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1567937076; called by muse, mutect2, varscan2
- NPAS1 | c.1603G>A p.G535S | Missense Mutation (SNP) | VAF 320/576 reads (56%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs1358209916; called by muse, mutect2, varscan2
- NRXN1 | c.4391C>T p.S1464F | Missense Mutation (SNP) | VAF 249/480 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV60513495, COSV60515579; called by muse, mutect2, varscan2
- NRXN3 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 428/535 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs765822699; called by muse, mutect2, varscan2
- NRXN3 | c.371G>A p.G124D (on ENST00000557594 / NM_001272020.2; = p.G756D on NM_004796.6) | Missense Mutation (SNP) | VAF 68/593 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs143930897; called by muse, mutect2, varscan2
- OBSCN | c.17758C>T p.R5920C | Missense Mutation (SNP) | VAF 211/575 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372074892; called by muse, mutect2, varscan2
- ODAM | c.142-1G>A p.X48_splice | Splice Site (SNP) | VAF 124/149 reads (83%) | catalogued as rs772957913; called by muse, mutect2, varscan2
- OGDHL | c.2516C>T p.P839L | Missense Mutation (SNP) | VAF 149/378 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200530979, COSV65104219; called by muse, mutect2, varscan2
- OPRM1 | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 246/365 reads (67%) | SIFT tolerated (0.5); PolyPhen benign (0.386); catalogued as rs187512719, COSV57674395; called by muse, mutect2, varscan2
- OPTN | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 208/492 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs888024328; called by muse, mutect2, varscan2
- OR14I1 | c.631C>T p.L211F | Missense Mutation (SNP) | VAF 93/264 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61199667; called by muse, mutect2, varscan2
- OR4D6 | c.405G>A p.M135I | Missense Mutation (SNP) | VAF 247/489 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55658945; called by muse, mutect2, varscan2
- OR4D6 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 90/474 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.818); catalogued as rs201015649; called by muse, mutect2
- OR4E2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 298/483 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201192739, COSV57731367; called by muse, mutect2
- OR5M1 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV73202117; called by muse, mutect2, varscan2
- OR6C68 | c.487C>T p.H163Y | Missense Mutation (SNP) | VAF 68/373 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV101110020, COSV65564269; called by muse, mutect2, varscan2
- OR6K6 | c.989G>A p.R330K (on ENST00000368144; = p.R306K on NM_001005184.1) | Missense Mutation (SNP) | VAF 105/282 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100933799; called by muse, varscan2
- OR8J2 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 102/200 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs1265174005; called by muse, mutect2, varscan2
- OR9G1 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 166/992 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV56450779; called by muse, mutect2
- OTOL1 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 179/325 reads (55%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100020227; called by muse, mutect2, varscan2
- PATE1 | c.77G>A p.R26K | Missense Mutation (SNP) | VAF 138/285 reads (48%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV59824348; called by muse, mutect2, varscan2
- PCDHA2 | c.1063C>G p.L355V | Missense Mutation (SNP) | VAF 58/228 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.414); catalogued as rs782551806; called by muse, mutect2, varscan2
- PCDHA3 | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 77/280 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782301588; called by muse, mutect2, varscan2
- PCDHB8 | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 66/723 reads (9%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.009); catalogued as COSV99177314; called by muse, mutect2
- PCDHGA3 | c.197T>A p.I66N | Missense Mutation (SNP) | VAF 81/316 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs772912037; called by muse, mutect2, varscan2
- PCLO | c.13796C>T p.S4599F | Missense Mutation (SNP) | VAF 225/343 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as COSV61616647; called by muse, mutect2, varscan2
- PFAS | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 81/684 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs758915573; called by muse, mutect2, varscan2
- PHLPP2 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 124/140 reads (89%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as rs762882143, COSV62423892; called by muse, mutect2, varscan2
- PHOSPHO1 | c.173G>A p.S58N | Missense Mutation (SNP) | VAF 414/730 reads (57%) | SIFT tolerated (0.52); PolyPhen benign (0.253); catalogued as rs1365965538; called by muse, varscan2
- PIK3AP1 | c.2027C>G p.T676R | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59531748; called by muse, mutect2, varscan2
- PNMA1 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 464/588 reads (79%) | SIFT tolerated (0.58); PolyPhen benign (0.212); catalogued as COSV99678959; called by muse, mutect2, varscan2
- POTEG | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 364/1492 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs145666754, COSV101611982; called by muse, mutect2
- PPP1R3A | c.2451G>A p.M817I | Missense Mutation (SNP) | VAF 237/431 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV52876950; called by muse, mutect2, varscan2
- PRIM1 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 257/342 reads (75%) | SIFT tolerated (0.32); PolyPhen benign (0.042); catalogued as rs201428535, COSV57717575; called by muse, mutect2, varscan2
- PRKDC | c.11590C>T p.R3864C | Missense Mutation (SNP) | VAF 132/198 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs377101643; called by muse, varscan2
- PRKDC | c.9860G>A p.R3287Q | Missense Mutation (SNP) | VAF 186/285 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as rs765440019, COSV100038414; called by muse, mutect2, varscan2
- PROM2 | c.1888G>T p.V630L | Missense Mutation (SNP) | VAF 311/593 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.055); catalogued as rs763434626; called by muse, mutect2, varscan2
- PRR32 | c.227G>A p.R76K | Missense Mutation (SNP) | VAF 291/312 reads (93%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV64420493; called by muse, mutect2, varscan2
- PRR36 | c.2959C>T p.P987S | Missense Mutation (SNP) | VAF 59/239 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs1173420222; called by muse, mutect2, varscan2
- PRRC2A | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 261/382 reads (68%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.996); catalogued as rs950589865; called by muse, mutect2, varscan2
- PRRC2C | c.6890C>T p.S2297L (on ENST00000367742; = p.S2295L on NM_015172.4) | Missense Mutation (SNP) | VAF 151/398 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV58902730; called by muse, mutect2, varscan2
- PTPRG | c.2005G>A p.D669N | Missense Mutation (SNP) | VAF 244/649 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs149537126; called by muse, mutect2, varscan2
- PTPRJ | c.3241C>T p.R1081C | Missense Mutation (SNP) | VAF 103/229 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1024704269; called by muse, mutect2, varscan2
- R3HDM2 | c.1579C>T p.P527S | Missense Mutation (SNP) | VAF 49/564 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as rs1467969609; called by muse, mutect2
- RASGRP3 | c.810C>T p.N270= | Splice Region (SNP) | VAF 103/275 reads (37%) | catalogued as rs768449180; called by muse, mutect2, varscan2
- RAX | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 519/724 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as rs778308289; called by muse, mutect2, varscan2
- RBM19 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 204/317 reads (64%) | SIFT tolerated (0.07); PolyPhen benign (0.3); catalogued as COSV55690449; called by muse, mutect2, varscan2
- RCC1L | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 478/837 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.51); catalogued as rs781836499; called by muse, mutect2, varscan2
- REG3A | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 173/344 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs779093650, COSV100532523, COSV59409425; called by muse, mutect2, varscan2
- RESP18 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 80/215 reads (37%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.475); catalogued as rs1277356000, COSV61113781; called by muse, mutect2, varscan2
- RGPD8 | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 25/236 reads (11%) | catalogued as COSV100221737, COSV56902423; called by muse, mutect2
- RIMS1 | c.3338G>A p.R1113K | Missense Mutation (SNP) | VAF 146/254 reads (57%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.933); catalogued as COSV53475353; called by muse, varscan2
- RNF175 | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 142/303 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs763159569; called by muse, mutect2, varscan2
- RP1 | c.2435C>T p.P812L | Missense Mutation (SNP) | VAF 177/213 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101587691; called by muse, mutect2, varscan2
- RTL1 | c.1759C>T p.L587F | Missense Mutation (SNP) | VAF 189/770 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV66017477; called by muse, mutect2, varscan2
- SART1 | c.22C>G p.R8G | Missense Mutation (SNP) | VAF 186/355 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); catalogued as COSV56711700, COSV56712123; called by muse, mutect2, varscan2
- SEMA3E | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 112/386 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV57080425; called by muse, varscan2
- SFTPA2 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 62/377 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs767317715, COSV64882540; called by muse, mutect2, varscan2
- SGSM1 | c.2485G>A p.E829K (on ENST00000400359 / NM_001039948.4; = p.E768K on NM_133454.3) | Missense Mutation (SNP) | VAF 282/619 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV63082814; called by muse, mutect2, varscan2
- SLC23A3 | c.1015G>A p.G339S | Missense Mutation (SNP) | VAF 119/321 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.365); catalogued as rs1238008734; called by muse, mutect2, varscan2
- SLC28A1 | c.462-1G>A p.X154_splice | Splice Site (SNP) | VAF 268/360 reads (74%) | catalogued as rs779453805, COSV99723269; called by muse, mutect2, varscan2
- SLC44A3 | c.979C>T p.P327S (on ENST00000271227 / NM_001114106.3; = p.P279S on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 385/428 reads (90%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); catalogued as rs756785788, COSV54732162; called by muse, mutect2, varscan2
- SLC44A5 | c.1470G>A p.M490I | Missense Mutation (SNP) | VAF 288/315 reads (91%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs138689403, COSV63758541; called by muse, mutect2, varscan2
- SLC6A3 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 279/462 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54361959; called by muse, varscan2
- SLC9A4 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 176/290 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs370821670; called by muse, mutect2, varscan2
- SPAST | c.684A>T p.E228D | Missense Mutation (SNP) | VAF 113/322 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.225); catalogued as rs1458104027; called by muse, mutect2, varscan2
- SPATA2 | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 207/838 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.948); catalogued as rs752675900; called by muse, mutect2, varscan2
- SPEG | c.9529C>T p.R3177C | Missense Mutation (SNP) | VAF 107/276 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs756642514, COSV100405005; called by muse, mutect2, varscan2
- SPOCK3 | c.940+4A>T | Splice Region (SNP) | VAF 122/215 reads (57%) | catalogued as COSV62732285; called by muse, mutect2, varscan2
- SPTA1 | c.5677G>A p.E1893K | Missense Mutation (SNP) | VAF 86/228 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.062); catalogued as COSV63750730; called by muse, mutect2, varscan2
- SSTR1 | c.1079G>A p.S360N | Missense Mutation (SNP) | VAF 76/370 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV57456379; called by muse, varscan2
- SUCO | c.3391G>A p.A1131T | Missense Mutation (SNP) | VAF 154/397 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV55269679; called by muse, mutect2, varscan2
- SYCE1 | c.550G>A p.E184K (on ENST00000343131 / NM_001143764.3; = p.E148K on NM_130784.3) | Missense Mutation (SNP) | VAF 83/373 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58217684; called by muse, mutect2, varscan2
- SYN3 | c.1312C>T p.P438S | Missense Mutation (SNP) | VAF 173/377 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs762240021; called by muse, mutect2, varscan2
- TARS2 | c.1519C>T p.L507F | Missense Mutation (SNP) | VAF 164/352 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.819); catalogued as COSV64695430; called by muse, mutect2, varscan2
- TCERG1 | c.1413_1417del p.E471Dfs*2 | Frame Shift Del (DEL) | VAF 39/115 reads (34%) | catalogued as rs781141103; called by pindel, varscan2
- TECPR1 | c.3086C>T p.P1029L | Missense Mutation (SNP) | VAF 250/422 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1172736194; called by muse, varscan2
- TEX43 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 80/158 reads (51%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as rs770263487, COSV64035944; called by muse, mutect2, varscan2
- TGM6 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 90/289 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs758286096, COSV52479822; called by muse, mutect2, varscan2
- TINAGL1 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 322/371 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54699454; called by muse, mutect2, varscan2
- TLR4 | c.2140C>T p.P714S (on ENST00000355622 / NM_138554.5; = p.P674S on NM_003266.4) | Missense Mutation (SNP) | VAF 436/491 reads (89%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV62922486; called by muse, mutect2, varscan2
- TMEM132A | c.2789G>A p.G930E (on ENST00000453848 / NM_178031.3; = p.G931E on NM_017870.4) | Missense Mutation (SNP) | VAF 404/756 reads (53%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.892); catalogued as rs1226949801; called by muse, mutect2, varscan2
- TMEM179 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 142/724 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.052); catalogued as rs1343248254, COSV58795240, COSV58795396; called by muse, mutect2, varscan2
- TMEM236 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 255/572 reads (45%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs1376489987; called by muse, mutect2, varscan2
- TNFRSF10B | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 171/273 reads (63%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs770017158; called by muse, mutect2, varscan2
- TNFRSF19 | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 135/267 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); catalogued as rs1408894457; called by muse, mutect2, varscan2
- TNN | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 169/527 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as rs755253081; called by muse, mutect2, varscan2
- TRIM49D1 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs755210364; called by muse, mutect2, varscan2
- TRPM4 | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 150/265 reads (57%) | catalogued as rs750176955, COSV99420688; called by muse, mutect2, varscan2
- TSKS | c.119C>T p.T40I | Missense Mutation (SNP) | VAF 93/331 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs773071788; called by muse, mutect2, varscan2
- TTN | c.24523G>A p.D8175N (on ENST00000591111; = p.D7248N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/596 reads (11%) | PolyPhen probably damaging (0.916); catalogued as rs770655555, COSV59902114; called by muse, mutect2, varscan2
- TTN | c.4678G>A p.E1560K (on ENST00000591111; = p.E1514K on NM_003319.4) | Missense Mutation (SNP) | VAF 346/413 reads (84%) | PolyPhen probably damaging (0.994); catalogued as COSV100594895; called by muse, mutect2, varscan2
- UBR4 | c.12419C>T p.A4140V | Missense Mutation (SNP) | VAF 258/307 reads (84%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.935); catalogued as rs1341280754; called by muse, mutect2, varscan2
- UBR4 | c.3130C>T p.R1044W | Missense Mutation (SNP) | VAF 228/271 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs766351812; called by muse, mutect2, varscan2
- UCP3 | c.181G>A p.V61M | Missense Mutation (SNP) | VAF 184/494 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.04); catalogued as rs146858543; called by muse, mutect2, varscan2
- UNC5D | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 150/246 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as rs1189500802, COSV54819138; called by muse, mutect2, varscan2
- USP6NL | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 118/309 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs984195074; called by muse, mutect2, varscan2
- VGLL2 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 123/495 reads (25%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs1264165017; called by muse, mutect2, varscan2
- WDR24 | c.1144G>A p.A382T (on ENST00000248142; = p.A252T on NM_032259.4) | Missense Mutation (SNP) | VAF 90/455 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as rs145838196; called by muse, mutect2, varscan2
- WDR87 | c.3875C>T p.P1292L | Missense Mutation (SNP) | VAF 220/322 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58208209; called by muse, mutect2, varscan2
- WDR87 | c.2998C>T p.R1000W | Missense Mutation (SNP) | VAF 111/167 reads (66%) | SIFT deleterious (0.04); PolyPhen benign (0.22); catalogued as rs376822850; called by muse, mutect2, varscan2
- ZACN | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 124/443 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.062); catalogued as rs898873151, COSV100135861; called by muse, mutect2, varscan2
- ZFHX2 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 85/452 reads (19%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs930794357; called by muse, mutect2, varscan2
- ZNF229 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 96/175 reads (55%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV52164960; called by muse, mutect2, varscan2
- ZNF256 | c.455G>A p.R152K | Missense Mutation (SNP) | VAF 83/320 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as COSV56596959; called by muse, mutect2, varscan2
- ZNF430 | c.824C>T p.T275I | Missense Mutation (SNP) | VAF 150/211 reads (71%) | SIFT tolerated (0.4); PolyPhen benign (0.082); catalogued as rs745938446; called by muse, mutect2, varscan2
- ZNF468 | c.1096C>T p.R366* | Nonsense Mutation (SNP) | VAF 61/186 reads (33%) | catalogued as rs138449706; called by muse, mutect2, varscan2
- ZNF611 | c.1652C>T p.S551F | Missense Mutation (SNP) | VAF 146/284 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs750313321, COSV60541758; called by muse, mutect2, varscan2
- ZNF628 | c.2831G>A p.G944D | Missense Mutation (SNP) | VAF 241/441 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs1173196992; called by muse, mutect2, varscan2
- ZNF710 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 90/700 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.027); catalogued as rs757423885, COSV51565867; called by muse, mutect2, varscan2
- ZNF804B | c.2185C>T p.H729Y | Missense Mutation (SNP) | VAF 252/434 reads (58%) | SIFT tolerated (0.5); PolyPhen benign (0.028); catalogued as COSV60832697; called by muse, mutect2, varscan2
- AATK | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 242/657 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- ABCA3 | c.4635G>A p.M1545I | Missense Mutation (SNP) | VAF 414/580 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ABCB9 | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 128/183 reads (70%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ACACB | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 292/422 reads (69%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACAD9 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 57/260 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ADAM12 | c.2561C>T p.P854L | Missense Mutation (SNP) | VAF 174/286 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAM2 | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ADAMTSL3 | c.3202G>A p.G1068R | Missense Mutation (SNP) | VAF 326/437 reads (75%) | SIFT tolerated (0.4); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADGRG4 | c.4078C>T p.L1360F | Missense Mutation (SNP) | VAF 238/274 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- AEBP2 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 229/282 reads (81%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- AFF3 | c.157T>G p.F53V | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AK9 | c.1067C>T p.S356F | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- AKT2 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 37/206 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ALKBH1 | c.635del p.F212Sfs*8 | Frame Shift Del (DEL) | VAF 69/584 reads (12%) | called by pindel, varscan2
- ANKRD31 | c.1975G>A p.E659K | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- AP5B1 | c.1508A>T p.H503L | Missense Mutation (SNP) | VAF 223/619 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- AP5Z1 | c.2008T>C p.F670L | Missense Mutation (SNP) | VAF 183/709 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- ARHGAP5 | c.2084C>T p.P695L | Missense Mutation (SNP) | VAF 54/264 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- AS3MT | c.914A>T p.E305V | Missense Mutation (SNP) | VAF 110/201 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- ASB1 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ASIC3 | c.1462C>T p.Q488* | Nonsense Mutation (SNP) | VAF 109/429 reads (25%) | called by muse, mutect2, varscan2
- ATMIN | c.1973C>T p.T658I | Missense Mutation (SNP) | VAF 254/276 reads (92%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- BARHL2 | c.860G>A p.W287* | Nonsense Mutation (SNP) | VAF 244/283 reads (86%) | called by muse, mutect2, varscan2
- BCAN | c.862G>A p.G288S | Missense Mutation (SNP) | VAF 181/566 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- BCL2L14 | c.788C>T p.S263L | Missense Mutation (SNP) | VAF 152/211 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- BCL9 | c.3649G>A p.D1217N | Missense Mutation (SNP) | VAF 151/397 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- BTNL9 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 69/235 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- C15orf40 | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 213/288 reads (74%) | SIFT tolerated (0.17); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- C17orf98 | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 139/434 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, varscan2
- C6orf15 | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 113/651 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- CACNA1E | c.5028G>T p.K1676N | Missense Mutation (SNP) | VAF 66/406 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.374); called by muse, varscan2
- CCDC168 | c.17860G>A p.E5954K | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- CCDC168 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CCDC61 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 257/454 reads (57%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- CCDC88A | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 108/309 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- CCN2 | c.737T>C p.L246P | Missense Mutation (SNP) | VAF 144/207 reads (70%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- CCR2 | c.800C>T p.T267I | Missense Mutation (SNP) | VAF 108/364 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- CCZ1 | c.1098G>T p.R366S | Missense Mutation (SNP) | VAF 91/114 reads (80%) | SIFT tolerated (0.27); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- CD36 | c.757T>C p.S253P | Missense Mutation (SNP) | VAF 173/320 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- CDC42BPG | c.2968C>T p.P990S | Missense Mutation (SNP) | VAF 152/491 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- CDH19 | c.836T>A p.M279K | Missense Mutation (SNP) | VAF 42/300 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CDH19 | c.835A>T p.M279L | Missense Mutation (SNP) | VAF 41/296 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH26 | c.1283G>C p.R428T | Missense Mutation (SNP) | VAF 39/301 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- CEACAM6 | c.76A>G p.T26A | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CHD8 | c.1559A>C p.K520T (on ENST00000646647 / NM_001170629.2; = p.K241T on NM_020920.4) | Missense Mutation (SNP) | VAF 269/400 reads (67%) | SIFT tolerated (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CHIC2 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 102/168 reads (61%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- CKMT2 | c.1249G>A p.G417S | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLDN8 | c.628C>T p.H210Y | Missense Mutation (SNP) | VAF 220/376 reads (59%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLIP2 | c.1320-3_1329del p.X440_splice | Splice Site (DEL) | VAF 92/199 reads (46%) | called by pindel, varscan2
- CNTROB | c.2053C>T p.P685S | Missense Mutation (SNP) | VAF 307/560 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- COL15A1 | c.3364C>T p.P1122S | Missense Mutation (SNP) | VAF 496/539 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL16A1 | c.2231C>T p.P744L | Missense Mutation (SNP) | VAF 435/487 reads (89%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COL4A3 | c.706G>A p.G236R | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A3 | c.707G>A p.G236E | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL8A1 | c.1615G>A p.G539R | Missense Mutation (SNP) | VAF 59/379 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL8A1 | c.1616G>A p.G539E | Missense Mutation (SNP) | VAF 59/377 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL9A2 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 376/433 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COLEC12 | c.2070G>A p.W690* | Nonsense Mutation (SNP) | VAF 52/338 reads (15%) | called by muse, mutect2, varscan2
- CPNE3 | c.1114T>A p.C372S | Missense Mutation (SNP) | VAF 126/334 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- CRELD2 | c.766T>A p.C256S | Missense Mutation (SNP) | VAF 228/476 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- CUL9 | c.1594A>T p.K532* | Nonsense Mutation (SNP) | VAF 62/335 reads (19%) | called by muse, mutect2, varscan2
- CYC1 | c.480A>T p.E160D | Missense Mutation (SNP) | VAF 216/316 reads (68%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYP27A1 | c.1025A>C p.N342T | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- CYP2A6 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 71/353 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- DGKI | c.1192A>C p.M398L | Missense Mutation (SNP) | VAF 48/443 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- DHX30 | c.292G>A p.E98K (on ENST00000445061 / NM_138615.3; = p.E59K on NM_014966.3) | Missense Mutation (SNP) | VAF 105/360 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- DIAPH1 | c.1967C>T p.P656L | Missense Mutation (SNP) | VAF 100/206 reads (49%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.017); called by muse, varscan2
- DIAPH3 | c.276C>A p.N92K | Missense Mutation (SNP) | VAF 129/252 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- DIDO1 | c.5506G>A p.G1836R | Missense Mutation (SNP) | VAF 170/636 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- DNAH10 | c.6274G>A p.V2092M (on ENST00000409039; = p.V2031M on NM_207437.3) | Missense Mutation (SNP) | VAF 72/415 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DNAJC18 | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 91/203 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOCK1 | c.4456G>A p.E1486K | Missense Mutation (SNP) | VAF 129/202 reads (64%) | SIFT tolerated (0.13); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- DOCK1 | c.5533C>T p.P1845S | Missense Mutation (SNP) | VAF 186/295 reads (63%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DST | c.5054C>T p.A1685V | Missense Mutation (SNP) | VAF 218/306 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- DZIP3 | c.286G>A p.G96S | Missense Mutation (SNP) | VAF 60/240 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- EBI3 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 144/310 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- EFCAB13 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 127/261 reads (49%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- EHD4 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 354/480 reads (74%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- EHMT2 | c.1772C>T p.P591L | Missense Mutation (SNP) | VAF 98/636 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- EIF3A | c.91C>T p.L31F | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ELOVL3 | c.500G>A p.G167E | Missense Mutation (SNP) | VAF 79/341 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- EPX | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 133/497 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- ERC2 | c.791_792insC p.R264Sfs*8 | Frame Shift Ins (INS) | VAF 136/428 reads (32%) | called by mutect2, pindel, varscan2
- ERFL | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 264/490 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- EXOC3 | c.731G>A p.W244* | Nonsense Mutation (SNP) | VAF 140/505 reads (28%) | called by muse, mutect2, varscan2
- FAM133A | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 257/278 reads (92%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- FAM155A | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 189/328 reads (58%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAT1 | c.5634_5635dup p.F1879Cfs*19 | Frame Shift Ins (INS) | VAF 257/694 reads (37%) | called by mutect2, pindel, varscan2
- FAT3 | c.2348T>C p.L783P | Missense Mutation (SNP) | VAF 167/321 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- FBXO30 | c.206T>C p.F69S | Missense Mutation (SNP) | VAF 192/294 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- FDPS | c.383T>C p.L128S | Missense Mutation (SNP) | VAF 98/333 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- FGD5 | c.1574C>T p.S525L | Missense Mutation (SNP) | VAF 135/447 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FN1 | c.5924C>T p.A1975V | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- FOXD4L5 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 441/1072 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); called by muse, varscan2
- FREM3 | c.4374T>A p.D1458E | Missense Mutation (SNP) | VAF 210/435 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- GALR3 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 252/511 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GART | c.2080C>G p.L694V | Missense Mutation (SNP) | VAF 89/158 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- GATA6 | c.1456G>C p.E486Q | Missense Mutation (SNP) | VAF 135/225 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- GLDC | c.1667G>A p.G556E | Missense Mutation (SNP) | VAF 113/129 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- GLI2 | c.2998G>A p.G1000S (on ENST00000361492 / NM_001374353.1; = p.G1017S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 137/677 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- GSDME | c.221_222del p.E74Vfs*79 | Frame Shift Del (DEL) | VAF 88/375 reads (23%) | called by mutect2, pindel, varscan2
- GTF2F1 | c.1436C>T p.T479I | Missense Mutation (SNP) | VAF 175/319 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GTPBP1 | c.1316C>T p.S439F | Missense Mutation (SNP) | VAF 249/557 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- GZF1 | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 120/216 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- HHIP | c.868C>T p.H290Y | Missense Mutation (SNP) | VAF 163/277 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HYDIN | c.14182C>T p.P4728S | Missense Mutation (SNP) | VAF 153/226 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IFNA10 | c.318A>T p.E106D | Missense Mutation (SNP) | VAF 209/304 reads (69%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IFNL2 | c.311T>C p.L104P | Missense Mutation (SNP) | VAF 100/338 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGBP1P2 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 143/492 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.331); called by muse, mutect2
- IGLC7 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 265/649 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- IGSF10 | c.1688C>T p.T563I | Missense Mutation (SNP) | VAF 214/329 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- IL7R | c.502G>C p.A168P | Missense Mutation (SNP) | VAF 85/281 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- INHBE | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 99/922 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- INPP5B | c.2266A>G p.K756E (on ENST00000373023; = p.K676E on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 278/307 reads (91%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INSR | c.1877T>G p.L626R | Missense Mutation (SNP) | VAF 91/147 reads (62%) | SIFT tolerated (0.95); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ITGB4 | c.3806C>T p.P1269L | Missense Mutation (SNP) | VAF 190/326 reads (58%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- JPH2 | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 412/704 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); called by muse, mutect2
- KIF4B | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 94/333 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHDC4 | c.1316T>G p.V439G | Missense Mutation (SNP) | VAF 468/532 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- KLHL30 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 95/281 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- KLRG2 | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 266/927 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- KMT2D | c.6806C>T p.S2269F | Missense Mutation (SNP) | VAF 374/547 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- KRT10 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 73/254 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LAMA5 | c.2735T>C p.V912A | Missense Mutation (SNP) | VAF 321/499 reads (64%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LPL | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 26/162 reads (16%) | called by muse, mutect2, varscan2
- LRPPRC | c.239C>A p.S80Y | Missense Mutation (SNP) | VAF 265/476 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- LTBP3 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 269/528 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- LTBP3 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 270/530 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- MAGEB3 | c.848C>A p.T283N | Missense Mutation (SNP) | VAF 302/331 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAP3K13 | c.1120G>A p.V374I | Missense Mutation (SNP) | VAF 48/270 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- MAP9 | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 196/346 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- MIEF1 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 132/361 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MIOX | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 165/330 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MLH3 | c.4018del p.Q1340Rfs*12 (on ENST00000355774 / NM_001040108.2; = p.Q1316Rfs*12 on NM_014381.3) | Frame Shift Del (DEL) | VAF 311/502 reads (62%) | called by mutect2, pindel, varscan2
- MLPH | c.874G>T p.A292S | Missense Mutation (SNP) | VAF 73/151 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MOBP | c.331C>T p.P111S (on ENST00000420739; = p.P135S on NM_001278322.2) | Missense Mutation (SNP) | VAF 203/769 reads (26%) | PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- MOBP | c.332C>T p.P111L (on ENST00000420739; = p.P135L on NM_001278322.2) | Missense Mutation (SNP) | VAF 207/769 reads (27%) | PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- MRGPRE | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 283/636 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MUC16 | c.25952G>A p.G8651E | Missense Mutation (SNP) | VAF 111/379 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- MUC5B | c.16926G>A p.G5642= | Splice Region (SNP) | VAF 96/461 reads (21%) | called by muse, mutect2, varscan2
- MYH4 | c.2144G>T p.S715I | Missense Mutation (SNP) | VAF 62/523 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); called by mutect2, varscan2
- MYO16 | c.4721C>T p.P1574L | Missense Mutation (SNP) | VAF 176/301 reads (58%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NCKAP5L | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 59/421 reads (14%) | called by muse, mutect2, varscan2
- NCOR2 | c.3199C>T p.P1067S | Missense Mutation (SNP) | VAF 374/558 reads (67%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NDST3 | c.650G>A p.G217E | Missense Mutation (SNP) | VAF 108/348 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NEO1 | c.988G>T p.E330* | Nonsense Mutation (SNP) | VAF 239/323 reads (74%) | called by muse, mutect2, varscan2
- NGFR | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 253/713 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- NLRP1 | c.3356T>G p.M1119R | Missense Mutation (SNP) | VAF 196/500 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- NLRP2 | c.2935A>C p.S979R | Missense Mutation (SNP) | VAF 132/415 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NOL8 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 471/508 reads (93%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NPIPB15 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- NR1D2 | c.763G>A p.G255S | Missense Mutation (SNP) | VAF 228/416 reads (55%) | SIFT tolerated (0.39); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- NUDT14 | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 90/442 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NUDT9 | c.583C>T p.H195Y | Missense Mutation (SNP) | VAF 97/115 reads (84%) | SIFT tolerated (0.07); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- OR2J3 | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 255/366 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- OR5W2 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 162/300 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- OR6C6 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 321/364 reads (88%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- OR6C75 | c.640C>T p.L214F | Missense Mutation (SNP) | VAF 43/269 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- OR8J2 | c.813C>A p.D271E | Missense Mutation (SNP) | VAF 94/308 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- OTC | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 122/150 reads (81%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PANX1 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 105/259 reads (41%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PAPLN | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 303/383 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PBRM1 | c.4009A>T p.I1337F | Missense Mutation (SNP) | VAF 252/472 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHB1 | c.2074G>A p.V692I | Missense Mutation (SNP) | VAF 67/264 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- PCDHGC5 | c.2011C>T p.P671S | Missense Mutation (SNP) | VAF 65/292 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.021); called by muse, varscan2
- PCYT2 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 162/404 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, varscan2
- PCYT2 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 177/424 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDE3A | c.1592A>G p.Q531R | Missense Mutation (SNP) | VAF 134/168 reads (80%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHF1 | c.688T>A p.Y230N | Missense Mutation (SNP) | VAF 267/374 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PKN1 | c.2335C>T p.P779S | Missense Mutation (SNP) | VAF 157/276 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLAGL2 | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 156/533 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- PLEKHD1 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 413/540 reads (76%) | called by muse, mutect2, varscan2
- PLEKHG1 | c.2366G>A p.S789N | Missense Mutation (SNP) | VAF 219/322 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- PNPT1 | c.1796C>T p.S599F | Missense Mutation (SNP) | VAF 101/339 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- POU2F1 | c.873T>A p.F291L (on ENST00000541643 / NM_001365848.1; = p.F314L on NM_002697.4) | Missense Mutation (SNP) | VAF 129/333 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PPP1R10 | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 104/559 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- PRR14L | c.6142T>C p.Y2048H | Missense Mutation (SNP) | VAF 66/187 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRR5L | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 90/246 reads (37%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRSS12 | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 405/774 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- PSMD2 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 102/178 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PTPRB | c.2824G>A p.A942T | Missense Mutation (SNP) | VAF 277/398 reads (70%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- PXMP2 | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 154/180 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- RAC2 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 184/406 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- RANGRF | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 222/603 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RASA3 | c.1781G>A p.G594E | Missense Mutation (SNP) | VAF 43/235 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RELN | c.9264T>G p.N3088K | Missense Mutation (SNP) | VAF 128/437 reads (29%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- REV3L | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 187/269 reads (70%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RRP1B | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 83/158 reads (53%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- RSPH9 | c.730T>C p.W244R | Missense Mutation (SNP) | VAF 369/544 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RYR2 | c.3260T>G p.I1087S | Missense Mutation (SNP) | VAF 100/293 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- SAMD7 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 162/258 reads (63%) | SIFT tolerated (0.25); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SATB2 | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 43/291 reads (15%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- SCN3A | c.2782G>A p.D928N | Missense Mutation (SNP) | VAF 344/503 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SEC16A | c.3274C>T p.Q1092* | Nonsense Mutation (SNP) | VAF 77/778 reads (10%) | called by muse, mutect2
- SENP1 | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SEPTIN6 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 211/231 reads (91%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- SHROOM2 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 406/429 reads (95%) | SIFT deleterious (0.01); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- SIMC1 | c.1045G>A p.G349R (on ENST00000443967 / NM_001308196.1; = p.G368R on NM_001308195.2) | Missense Mutation (SNP) | VAF 145/336 reads (43%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SIRT7 | c.547del p.I183Sfs*28 | Frame Shift Del (DEL) | VAF 176/365 reads (48%) | called by mutect2, pindel*, varscan2
- SLC16A12 | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 47/211 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- SLC22A3 | c.700G>T p.V234L | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- SLC23A3 | c.1016G>A p.G339D | Missense Mutation (SNP) | VAF 124/324 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- SLC24A1 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 62/371 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SLC5A5 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 112/195 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- SLC9A3R1 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 47/442 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- SLCO4A1 | c.522_525dup p.G176Lfs*24 | Frame Shift Ins (INS) | VAF 158/744 reads (21%) | called by mutect2, pindel, varscan2
- SLITRK3 | c.1757T>C p.V586A | Missense Mutation (SNP) | VAF 204/310 reads (66%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); called by muse, varscan2
- SLX4 | c.4022G>A p.R1341K | Missense Mutation (SNP) | VAF 87/534 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SMARCAL1 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 70/219 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- SNX8 | c.704T>A p.L235H | Missense Mutation (SNP) | VAF 60/529 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SOX1 | c.328C>G p.L110V | Missense Mutation (SNP) | VAF 115/396 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- SPAG1 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 81/220 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- SPATA31D1 | c.4718C>T p.P1573L | Missense Mutation (SNP) | VAF 171/208 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- SPEG | c.8366C>T p.S2789L | Missense Mutation (SNP) | VAF 102/267 reads (38%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- SPHKAP | c.4753G>A p.G1585R (on ENST00000392056 / NM_001142644.2; = p.G1556R on NM_030623.3) | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- SPINK5 | c.1786C>T p.H596Y | Missense Mutation (SNP) | VAF 54/244 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- SRCIN1 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 187/384 reads (49%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- SRRM3 | c.1913C>T p.P638L | Missense Mutation (SNP) | VAF 220/744 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- SSTR1 | c.176T>C p.I59T | Missense Mutation (SNP) | VAF 105/474 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- SSU72P3 | c.290G>A p.R97K | Missense Mutation (SNP) | VAF 158/510 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.699); called by muse, varscan2
- STK32B | c.765G>A p.M255I | Missense Mutation (SNP) | VAF 322/421 reads (76%) | SIFT tolerated (0.21); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- STRADA | c.1022C>T p.S341F (on ENST00000336174 / NM_001363786.1; = p.S304F on NM_153335.6) | Missense Mutation (SNP) | VAF 326/504 reads (65%) | SIFT tolerated (0.09); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SULT6B1 | c.644A>C p.K215T (on ENST00000535679 / NM_001367551.1; = p.K177T on NM_001032377.2) | Missense Mutation (SNP) | VAF 122/357 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- SUSD3 | c.487C>T p.L163F | Missense Mutation (SNP) | VAF 457/500 reads (91%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- SVIL | c.94C>G p.H32D | Missense Mutation (SNP) | VAF 224/502 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SYNGR1 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 320/698 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.364); called by muse, varscan2
- SZT2 | c.5287C>T p.L1763F (on ENST00000634258 / NM_001365999.1; = p.L1706F on NM_015284.4) | Missense Mutation (SNP) | VAF 238/274 reads (87%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- TAF3 | c.1631G>A p.R544K | Missense Mutation (SNP) | VAF 121/268 reads (45%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TBC1D30 | c.772-1G>A p.X258_splice (on ENST00000542120; = p.X95_splice on NM_015279.2 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 136/186 reads (73%) | called by muse, mutect2, varscan2
- THBS1 | c.31T>C p.F11L | Missense Mutation (SNP) | VAF 52/392 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- THBS1 | c.998T>C p.V333A | Missense Mutation (SNP) | VAF 63/385 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- TIAM2 | c.4727G>A p.G1576E (on ENST00000529824; = p.G1547E on NM_012454.3) | Missense Mutation (SNP) | VAF 257/422 reads (61%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TIMM21 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 58/78 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- TMEM18 | c.170T>A p.L57Q | Missense Mutation (SNP) | VAF 95/310 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TMEM240 | c.318G>A p.W106* | Nonsense Mutation (SNP) | VAF 663/716 reads (93%) | called by muse, mutect2, varscan2
- TMEM71 | c.482G>A p.G161E (on ENST00000523829 / NM_001382398.1; = p.G142E on NM_144649.3) | Missense Mutation (SNP) | VAF 133/235 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMPRSS15 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 122/370 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TOM1 | c.485T>G p.I162S | Missense Mutation (SNP) | VAF 174/421 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- TP53 | c.467_470delinsTTG p.R156Lfs*14 | Frame Shift Del (DEL) | VAF 202/673 reads (30%) | called by pindel, varscan2*
- TPH1 | c.562C>T p.H188Y | Missense Mutation (SNP) | VAF 105/249 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- TPTE2 | c.634T>C p.Y212H (on ENST00000400230 / NM_199254.2; = p.Y135H on NM_130785.3) | Missense Mutation (SNP) | VAF 73/163 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRABD2A | c.223A>C p.K75Q | Missense Mutation (SNP) | VAF 286/504 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRAJ19 | c.18C>A p.Y6* | Nonsense Mutation (SNP) | VAF 156/250 reads (62%) | called by muse, mutect2, varscan2
- TRAV9-2 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 48/321 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- TRIB2 | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 302/541 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIB2 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 302/543 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM58 | c.423A>G p.V141= | Splice Region (SNP) | VAF 74/224 reads (33%) | called by muse, mutect2, varscan2
- TRIP12 | c.4199C>T p.P1400L | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TTC17 | c.3151G>A p.D1051N | Missense Mutation (SNP) | VAF 106/226 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TTC9C | c.358C>T p.H120Y | Missense Mutation (SNP) | VAF 100/308 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- TTLL6 | c.827G>T p.C276F | Missense Mutation (SNP) | VAF 78/421 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.61028G>A p.G20343E (on ENST00000591111; = p.G12919E on NM_003319.4) | Missense Mutation (SNP) | VAF 455/548 reads (83%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TUB | c.73C>T p.Q25* (on ENST00000299506 / NM_177972.3; = p.Q80* on NM_003320.4) | Nonsense Mutation (SNP) | VAF 98/253 reads (39%) | called by muse, mutect2, varscan2
- TYW1 | c.1229C>T p.T410I | Missense Mutation (SNP) | VAF 220/451 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- UNC5D | c.2561C>T p.P854L | Missense Mutation (SNP) | VAF 206/350 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- URGCP | c.976G>A p.D326N (on ENST00000453200 / NM_001077663.3; = p.D317N on NM_017920.4) | Missense Mutation (SNP) | VAF 338/530 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- USP40 | c.1518G>A p.M506I | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- USP9Y | c.3585A>T p.Q1195H | Missense Mutation (SNP) | VAF 131/148 reads (89%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- VCX3B | c.376C>T p.Q126* | Nonsense Mutation (SNP) | VAF 244/515 reads (47%) | called by muse, varscan2
- WDR6 | c.2272C>T p.P758S | Missense Mutation (SNP) | VAF 164/480 reads (34%) | SIFT tolerated (0.98); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- WDR87 | c.6924G>C p.E2308D | Missense Mutation (SNP) | VAF 103/440 reads (23%) | SIFT tolerated, low confidence (0.42); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- WDR90 | c.3780G>A p.W1260* | Nonsense Mutation (SNP) | VAF 423/621 reads (68%) | called by muse, mutect2, varscan2
- WIPI2 | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 49/353 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- WNK2 | c.4519G>T p.A1507S (on ENST00000297954 / NM_001282394.1; = p.A1470S on NM_006648.3) | Missense Mutation (SNP) | VAF 246/1048 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- WT1 | c.892A>T p.N298Y | Missense Mutation (SNP) | VAF 1367/1491 reads (92%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- XKR4 | c.1420C>T p.L474F | Missense Mutation (SNP) | VAF 153/394 reads (39%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZDBF2 | c.6478C>T p.P2160S | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF107 | c.1552C>T p.H518Y | Missense Mutation (SNP) | VAF 238/434 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- ZNF214 | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 92/251 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF229 | c.922C>T p.L308F | Missense Mutation (SNP) | VAF 84/294 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- ZNF282 | c.1312A>T p.N438Y | Missense Mutation (SNP) | VAF 215/716 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF407 | c.6418G>C p.G2140R | Missense Mutation (SNP) | VAF 102/572 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- ZNF438 | c.692A>T p.Q231L | Missense Mutation (SNP) | VAF 217/471 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNF555 | c.1162A>G p.R388G | Missense Mutation (SNP) | VAF 64/207 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- ZNF628 | c.2830G>A p.G944S | Missense Mutation (SNP) | VAF 239/439 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- ZNF710 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 91/705 reads (13%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF804A | c.1784G>A p.R595K | Missense Mutation (SNP) | VAF 240/320 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2
- ZNF862 | c.137-1G>A p.X46_splice | Splice Site (SNP) | VAF 159/283 reads (56%) | called by muse, mutect2, varscan2
- ZSWIM5 | c.1335G>A p.W445* | Nonsense Mutation (SNP) | VAF 366/417 reads (88%) | called by muse, mutect2, varscan2
- ZSWIM8 | c.4391G>A p.G1464E (on ENST00000605216 / NM_001242487.2; = p.G1469E on NM_015037.3) | Missense Mutation (SNP) | VAF 328/503 reads (65%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZZEF1 | c.6038A>G p.E2013G | Missense Mutation (SNP) | VAF 167/426 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABHD11 | c.894C>T p.I298= | Silent (SNP) | VAF 247/440 reads (56%) | called by muse, mutect2, varscan2
- ABLIM3 | c.1503G>A p.R501= | Silent (SNP) | VAF 45/177 reads (25%) | called by muse, mutect2, varscan2
- ACKR1 | c.345C>G p.V115= | Silent (SNP) | VAF 205/570 reads (36%) | called by muse, mutect2, varscan2
- ADAM29 | c.2028C>T p.F676= | Silent (SNP) | VAF 85/339 reads (25%) | called by muse, mutect2, varscan2
- ADAMTS19 | c.3537C>T p.C1179= | Silent (SNP) | VAF 92/175 reads (53%) | catalogued as rs753897249; called by muse, mutect2, varscan2
- ADAMTS3 | c.3247C>T p.L1083= | Silent (SNP) | VAF 204/241 reads (85%) | catalogued as COSV54402930; called by muse, mutect2, varscan2
- ADAR | c.489G>A p.G163= | Silent (SNP) | VAF 216/428 reads (50%) | called by muse, mutect2, varscan2
- ADGRV1 | c.2428C>T p.L810= | Silent (SNP) | VAF 66/209 reads (32%) | called by muse, mutect2, varscan2
- ADH1C | c.501G>A p.L167= | Silent (SNP) | VAF 151/459 reads (33%) | called by muse, mutect2, varscan2
- AFG3L2 | c.2185C>T p.L729= | Silent (SNP) | VAF 116/188 reads (62%) | catalogued as rs752028185; called by muse, mutect2, varscan2
- AHNAK | c.14238G>A p.V4746= | Silent (SNP) | VAF 245/448 reads (55%) | called by muse, mutect2, varscan2
- AKAP9 | c.9795A>G p.E3265= (on ENST00000359028; = p.E3241= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 105/292 reads (36%) | catalogued as COSV62349674; called by muse, mutect2, varscan2
- ALK | c.3583C>T p.L1195= | Silent (SNP) | VAF 155/465 reads (33%) | called by muse, mutect2, varscan2
- AMT | c.48G>A p.Q16= | Silent (SNP) | VAF 157/430 reads (37%) | called by muse, mutect2, varscan2
- ANGPT1 | c.303G>A p.E101= | Silent (SNP) | VAF 33/240 reads (14%) | called by muse, varscan2
- ANGPTL1 | c.420G>A p.E140= | Silent (SNP) | VAF 120/361 reads (33%) | called by muse, mutect2, varscan2
- ANKRD12 | c.5193C>T p.I1731= | Silent (SNP) | VAF 159/216 reads (74%) | catalogued as COSV100041375; called by muse, mutect2, varscan2
- ANKRD35 | c.2280C>T p.S760= | Silent (SNP) | VAF 178/564 reads (32%) | called by muse, mutect2, varscan2
- ARPP21 | c.1080G>A p.R360= | Silent (SNP) | VAF 128/392 reads (33%) | catalogued as COSV104386479; called by muse, mutect2, varscan2
- ASAH2 | c.1683G>A p.G561= | Silent (SNP) | VAF 156/349 reads (45%) | called by muse, mutect2, varscan2
- ASCC2 | c.1068C>T p.S356= | Silent (SNP) | VAF 169/416 reads (41%) | called by muse, mutect2, varscan2
- ASTN2 | c.612C>T p.I204= | Silent (SNP) | VAF 242/280 reads (86%) | called by muse, mutect2, varscan2
- ATP1A4 | c.2424G>A p.L808= | Silent (SNP) | VAF 110/363 reads (30%) | called by muse, mutect2, varscan2
- ATP1B3 | c.333G>A p.K111= | Silent (SNP) | VAF 145/202 reads (72%) | called by muse, mutect2, varscan2
- ATP2A1 | c.873G>A p.G291= | Silent (SNP) | VAF 263/363 reads (72%) | called by muse, varscan2
- ATP2B4 | c.579C>T p.I193= | Silent (SNP) | VAF 137/369 reads (37%) | called by muse, mutect2, varscan2
- B3GNTL1 | c.447C>T p.S149= | Silent (SNP) | VAF 272/540 reads (50%) | called by muse, mutect2, varscan2
- BBS4 | c.1554G>A p.E518= | Silent (SNP) | VAF 123/158 reads (78%) | catalogued as rs752394112; called by muse, mutect2, varscan2
- BFAR | c.1191C>T p.F397= | Silent (SNP) | VAF 90/611 reads (15%) | called by muse, mutect2, varscan2
- BIRC6 | c.11146C>T p.L3716= | Silent (SNP) | VAF 190/509 reads (37%) | called by muse, mutect2, varscan2
- BMP1 | c.324C>T p.A108= | Silent (SNP) | VAF 66/344 reads (19%) | catalogued as COSV59244083; called by muse, mutect2, varscan2
- BTNL9 | c.684C>T p.S228= | Silent (SNP) | VAF 69/235 reads (29%) | called by muse, mutect2, varscan2
- C15orf39 | c.2724T>A p.I908= | Silent (SNP) | VAF 77/537 reads (14%) | called by muse, mutect2, varscan2
- C8orf34 | c.387C>T p.D129= | Silent (SNP) | VAF 145/232 reads (63%) | catalogued as rs1379014178; called by muse, varscan2
- C8orf48 | c.519G>A p.L173= | Silent (SNP) | VAF 200/311 reads (64%) | catalogued as rs945374415; called by muse, mutect2, varscan2
- CC2D2B | c.951A>G p.Q317= | Silent (SNP) | VAF 185/272 reads (68%) | called by muse, mutect2, varscan2
- CCDC141 | c.3552C>T p.S1184= | Silent (SNP) | VAF 450/545 reads (83%) | catalogued as rs1278132487; called by muse, mutect2, varscan2
- CCDC141 | c.2982G>A p.V994= | Silent (SNP) | VAF 308/415 reads (74%) | catalogued as COSV55369892; called by muse, mutect2, varscan2
- CCDC182 | c.360G>A p.P120= | Silent (SNP) | VAF 131/527 reads (25%) | catalogued as rs781563994; called by muse, mutect2, varscan2
- CCDC62 | c.967C>T p.L323= | Silent (SNP) | VAF 33/183 reads (18%) | called by muse, mutect2, varscan2
- CCR2 | c.801C>T p.T267= | Silent (SNP) | VAF 105/361 reads (29%) | called by muse, mutect2, varscan2
- CD84 | c.192A>G p.T64= | Silent (SNP) | VAF 123/354 reads (35%) | called by muse, mutect2, varscan2
- CHPF2 | c.876G>A p.E292= | Silent (SNP) | VAF 246/418 reads (59%) | called by muse, mutect2, varscan2
- CHPT1 | c.243C>T p.L81= | Silent (SNP) | VAF 347/498 reads (70%) | called by muse, mutect2, varscan2
- CIC | c.147G>A p.Q49= | Silent (SNP) | VAF 213/419 reads (51%) | called by muse, mutect2, varscan2
- CIC | c.4344C>T p.D1448= | Silent (SNP) | VAF 56/234 reads (24%) | catalogued as rs377587490, COSV99031257; called by muse, mutect2, varscan2
- CLUAP1 | c.933C>T p.N311= | Silent (SNP) | VAF 24/214 reads (11%) | catalogued as rs750353977, COSV58895516; called by muse, mutect2, varscan2
- CNTN2 | c.1506C>T p.I502= | Silent (SNP) | VAF 112/257 reads (44%) | catalogued as rs1186028093, COSV100085411; called by muse, mutect2, varscan2
- CNTN2 | c.1740C>T p.R580= | Silent (SNP) | VAF 179/345 reads (52%) | catalogued as rs199872560; called by muse, mutect2, varscan2
- COL15A1 | c.3363C>T p.G1121= | Silent (SNP) | VAF 454/494 reads (92%) | catalogued as COSV66643357; called by muse, varscan2
- CPA3 | c.297G>A p.E99= | Silent (SNP) | VAF 101/161 reads (63%) | catalogued as rs1157828534; called by muse, mutect2, varscan2
- DAO | c.579C>T p.P193= | Silent (SNP) | VAF 51/325 reads (16%) | catalogued as COSV57321483; called by muse, mutect2, varscan2
- DDX42 | c.1794C>T p.A598= | Silent (SNP) | VAF 254/454 reads (56%) | catalogued as rs142758870, COSV63789533; called by muse, mutect2, varscan2
- DENND1B | c.2037C>T p.D679= | Silent (SNP) | VAF 69/374 reads (18%) | called by muse, mutect2, varscan2
- DENND1B | c.1482G>A p.K494= | Silent (SNP) | VAF 95/219 reads (43%) | called by muse, mutect2, varscan2
- DHX35 | c.1707C>T p.F569= | Silent (SNP) | VAF 170/263 reads (65%) | catalogued as COSV52668201, COSV52671914; called by muse, mutect2, varscan2
- DMD | c.4164C>T p.F1388= | Silent (SNP) | VAF 224/237 reads (95%) | catalogued as COSV63744786; called by muse, mutect2, varscan2
- DMKN | c.915C>T p.S305= | Silent (SNP) | VAF 387/519 reads (75%) | catalogued as COSV100303455; called by muse, mutect2, varscan2
- DMP1 | c.903C>T p.S301= | Silent (SNP) | VAF 199/225 reads (88%) | called by muse, mutect2, varscan2
- DNAH11 | c.9063C>T p.S3021= | Silent (SNP) | VAF 188/343 reads (55%) | catalogued as rs368820581; called by muse, mutect2, varscan2
- DNMT3B | c.1479G>T p.T493= | Silent (SNP) | VAF 201/318 reads (63%) | called by muse, mutect2, varscan2
- DUSP8 | c.1443G>A p.R481= | Silent (SNP) | VAF 165/331 reads (50%) | catalogued as rs1334982484; called by muse, mutect2, varscan2
- DYNC1H1 | c.8469G>A p.R2823= | Silent (SNP) | VAF 116/511 reads (23%) | called by muse, mutect2, varscan2
- DYNC2I1 | c.402C>T p.L134= | Silent (SNP) | VAF 364/591 reads (62%) | called by muse, mutect2, varscan2
- EFCAB14 | c.1287C>T p.S429= | Silent (SNP) | VAF 202/228 reads (89%) | called by muse, mutect2, varscan2
- EFCAB8 | c.2238G>A p.P746= | Silent (SNP) | VAF 112/408 reads (27%) | catalogued as rs746382926; called by muse, mutect2, varscan2
- EIPR1 | c.786C>T p.T262= | Silent (SNP) | VAF 229/408 reads (56%) | catalogued as rs779480832; called by muse, mutect2, varscan2
- ENTR1 | c.189C>G p.P63= | Silent (SNP) | VAF 61/569 reads (11%) | called by muse, mutect2, varscan2
- ERI2 | c.216G>A p.Q72= | Silent (SNP) | VAF 62/391 reads (16%) | called by muse, mutect2, varscan2
- ESR2 | c.1218C>G p.L406= | Silent (SNP) | VAF 50/316 reads (16%) | called by muse, mutect2, varscan2
- EXOC4 | c.258C>T p.S86= | Silent (SNP) | VAF 191/328 reads (58%) | called by muse, mutect2, varscan2
- F13A1 | c.468G>A p.G156= | Silent (SNP) | VAF 347/511 reads (68%) | called by muse, mutect2, varscan2
- FAM205A | c.2196G>A p.L732= | Silent (SNP) | VAF 67/457 reads (15%) | catalogued as rs1755267; called by muse, mutect2, varscan2
- FAM217A | c.672G>A p.L224= | Silent (SNP) | VAF 60/388 reads (15%) | catalogued as COSV51159413; called by muse, mutect2, varscan2
- FAT3 | c.12210G>A p.R4070= | Silent (SNP) | VAF 135/390 reads (35%) | catalogued as COSV53189407; called by muse, mutect2, varscan2
- FER1L6 | c.1113C>T p.P371= | Silent (SNP) | VAF 162/353 reads (46%) | called by muse, mutect2, varscan2
- FGF1 | c.201G>A p.G67= | Silent (SNP) | VAF 104/206 reads (50%) | catalogued as rs1165372402; called by muse, mutect2, varscan2
- FIGNL1 | c.1665C>T p.A555= | Silent (SNP) | VAF 256/406 reads (63%) | called by muse, mutect2, varscan2
- FSIP2 | c.5202G>A p.A1734= | Silent (SNP) | VAF 49/463 reads (11%) | catalogued as rs568599074, COSV58084044; called by muse, mutect2, varscan2
- FSIP2 | c.14646A>G p.K4882= | Silent (SNP) | VAF 45/355 reads (13%) | called by muse, mutect2, varscan2
- GABRB1 | c.294T>A p.S98= | Silent (SNP) | VAF 43/344 reads (13%) | called by muse, varscan2
- GAMT | c.423G>A p.E141= | Silent (SNP) | VAF 124/238 reads (52%) | called by muse, mutect2, varscan2
- GAPVD1 | c.1569C>T p.P523= | Silent (SNP) | VAF 286/323 reads (89%) | called by muse, mutect2, varscan2
- GART | c.2079C>T p.V693= | Silent (SNP) | VAF 91/160 reads (57%) | called by muse, mutect2, varscan2
- GBA3 | c.423C>T p.S141= | Silent (SNP) | VAF 51/354 reads (14%) | catalogued as COSV101545524, COSV72437850; called by muse, mutect2, varscan2
- GLCE | c.255C>T p.P85= | Silent (SNP) | VAF 60/392 reads (15%) | catalogued as rs371241193; called by muse, mutect2, varscan2
- GLP1R | c.6C>T p.A2= | Silent (SNP) | VAF 50/380 reads (13%) | called by mutect2, varscan2
- GMIP | c.1671C>T p.P557= | Silent (SNP) | VAF 126/244 reads (52%) | called by muse, mutect2, varscan2
- GOLGA6L7 | c.516G>A p.R172= | Silent (SNP) | VAF 137/179 reads (77%) | called by muse, mutect2, varscan2
- GPD1L | c.690C>T p.I230= | Silent (SNP) | VAF 245/483 reads (51%) | called by muse, mutect2, varscan2
- GPR65 | c.372C>T p.F124= | Silent (SNP) | VAF 63/510 reads (12%) | catalogued as rs755830314, COSV50864553; called by muse, mutect2, varscan2
- GRID1 | c.1668C>T p.S556= | Silent (SNP) | VAF 51/277 reads (18%) | catalogued as rs146184813; called by muse, mutect2, varscan2
- GRIK2 | c.1458G>A p.G486= | Silent (SNP) | VAF 61/267 reads (23%) | catalogued as rs867832831, COSV59715366; called by muse, mutect2, varscan2
- H3C4 | c.405G>A p.R135= | Silent (SNP) | VAF 19/208 reads (9%) | catalogued as rs184040601, COSV100587054; called by muse, mutect2, varscan2
- HABP2 | c.666C>T p.L222= | Silent (SNP) | VAF 197/341 reads (58%) | catalogued as COSV63637700; called by muse, mutect2, varscan2
- HEATR6 | c.2512C>T p.L838= | Silent (SNP) | VAF 149/262 reads (57%) | catalogued as COSV99482457; called by muse, mutect2, varscan2
- HERC2 | c.9993G>A p.T3331= | Silent (SNP) | VAF 54/1059 reads (5%) | catalogued as rs754278624, COSV55305319; called by muse, mutect2
- HFM1 | c.2793C>T p.S931= | Silent (SNP) | VAF 138/164 reads (84%) | called by muse, mutect2, varscan2
- HTR1B | c.813C>T p.N271= | Silent (SNP) | VAF 226/337 reads (67%) | called by muse, mutect2, varscan2
- IBA57 | c.297C>T p.F99= | Silent (SNP) | VAF 324/636 reads (51%) | catalogued as COSV64510799; called by muse, mutect2, varscan2
- IGLV1-44 | c.12C>T p.F4= | Silent (SNP) | VAF 163/343 reads (48%) | catalogued as rs772791590; called by muse, mutect2, varscan2
- IL1RL1 | c.210A>G p.Q70= | Silent (SNP) | VAF 70/344 reads (20%) | catalogued as rs770243947; called by muse, mutect2, varscan2
- IPCEF1 | c.1026C>T p.S342= | Silent (SNP) | VAF 193/318 reads (61%) | called by muse, mutect2, varscan2
- ITGB4 | c.3807C>T p.P1269= | Silent (SNP) | VAF 198/336 reads (59%) | catalogued as CD056463; called by muse, mutect2, varscan2
- ITGB7 | c.420C>T p.L140= | Silent (SNP) | VAF 56/408 reads (14%) | called by muse, mutect2, varscan2
- KALRN | c.1701G>A p.G567= | Silent (SNP) | VAF 180/267 reads (67%) | catalogued as COSV53763793; called by muse, mutect2, varscan2
- KATNAL2 | c.1248G>A p.K416= (on ENST00000356157 / NM_001353899.1; = p.K344= on NM_031303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 222/329 reads (67%) | called by muse, mutect2, varscan2
- KAZN | c.1872C>T p.I624= | Silent (SNP) | VAF 283/322 reads (88%) | catalogued as rs1347753244; called by muse, mutect2, varscan2
- KCNC3 | c.1020G>A p.V340= | Silent (SNP) | VAF 94/354 reads (27%) | called by muse, mutect2, varscan2
- KCNK5 | c.678C>T p.F226= | Silent (SNP) | VAF 206/288 reads (72%) | catalogued as rs1017757180, COSV100851769; called by muse, mutect2, varscan2
- KDM1B | c.1218T>C p.I406= (on ENST00000449850; = p.I274= on NM_153042.4) | Silent (SNP) | VAF 41/249 reads (16%) | called by muse, mutect2, varscan2
- KIF19 | c.2301C>T p.S767= | Silent (SNP) | VAF 85/388 reads (22%) | called by muse, mutect2, varscan2
- KIF4B | c.3636G>A p.K1212= | Silent (SNP) | VAF 113/221 reads (51%) | called by muse, mutect2, varscan2
- KIR2DL3 | c.360C>T p.I120= | Silent (SNP) | VAF 27/192 reads (14%) | catalogued as rs771556841, COSV60897767; called by muse, mutect2, varscan2
- KLF18 | c.1143C>T p.S381= | Silent (SNP) | VAF 345/479 reads (72%) | called by muse, varscan2
- KLHL30 | c.1059G>A p.K353= | Silent (SNP) | VAF 95/280 reads (34%) | called by muse, mutect2, varscan2
- KLRG2 | c.333G>A p.G111= | Silent (SNP) | VAF 264/925 reads (29%) | called by muse, mutect2, varscan2
- LENG8 | c.1632C>T p.D544= | Silent (SNP) | VAF 317/562 reads (56%) | catalogued as rs1376344878; called by muse, mutect2, varscan2
- LINC02218 | c.459G>A p.V153= | Silent (SNP) | VAF 126/454 reads (28%) | called by muse, varscan2
- LMOD1 | c.480G>A p.K160= | Silent (SNP) | VAF 201/538 reads (37%) | catalogued as COSV100939298; called by muse, mutect2, varscan2
- LRP1 | c.7728G>A p.G2576= | Silent (SNP) | VAF 509/607 reads (84%) | catalogued as COSV54510779; called by muse, mutect2, varscan2
- LRRC37A | c.4188C>T p.A1396= | Silent (SNP) | VAF 87/441 reads (20%) | catalogued as COSV100208110; called by muse, mutect2, varscan2
- LRRC37A2 | c.4188C>T p.A1396= | Silent (SNP) | VAF 88/554 reads (16%) | called by muse, mutect2, varscan2
- LRRC37A3 | c.1116G>A p.E372= | Silent (SNP) | VAF 263/1635 reads (16%) | catalogued as rs1433969301; called by muse, mutect2, varscan2
- LRRIQ1 | c.3708C>T p.A1236= | Silent (SNP) | VAF 52/397 reads (13%) | catalogued as COSV101279407, COSV67833467; called by muse, mutect2, varscan2
- MACC1 | c.819G>A p.L273= | Silent (SNP) | VAF 82/322 reads (25%) | called by muse, mutect2, varscan2
- MAGEL2 | c.1416C>T p.I472= | Silent (SNP) | VAF 661/1100 reads (60%) | called by muse, mutect2, varscan2
- MAN2C1 | c.1875C>T p.L625= | Silent (SNP) | VAF 110/590 reads (19%) | catalogued as rs576306046; called by muse, mutect2, varscan2
- MAPK7 | c.1953C>T p.V651= | Silent (SNP) | VAF 436/1044 reads (42%) | catalogued as COSV55190153; called by muse, mutect2, varscan2
- MAPK9 | c.174C>T p.S58= | Silent (SNP) | VAF 42/193 reads (22%) | called by muse, mutect2, varscan2
- MCCC1 | c.1395C>T p.T465= | Silent (SNP) | VAF 124/194 reads (64%) | called by muse, mutect2, varscan2
- MCM10 | c.1842C>T p.F614= (on ENST00000484800 / NM_182751.3; = p.F613= on NM_018518.5) | Silent (SNP) | VAF 204/437 reads (47%) | catalogued as rs1317676596, COSV66336771; called by muse, mutect2, varscan2
- MED16 | c.210C>T p.P70= | Silent (SNP) | VAF 109/218 reads (50%) | catalogued as rs139294457; called by muse, mutect2, varscan2
- MED9 | c.15G>A p.G5= | Silent (SNP) | VAF 329/643 reads (51%) | catalogued as rs778963066; called by muse, mutect2, varscan2
- MFAP3L | c.627C>T p.P209= | Silent (SNP) | VAF 124/400 reads (31%) | called by muse, mutect2, varscan2
- MGAM | c.2940C>A p.A980= | Silent (SNP) | VAF 221/365 reads (61%) | called by muse, mutect2, varscan2
- MIEF1 | c.168C>T p.A56= | Silent (SNP) | VAF 128/356 reads (36%) | catalogued as rs745489780; called by muse, mutect2, varscan2
- MSR1 | c.195C>T p.I65= | Silent (SNP) | VAF 208/321 reads (65%) | catalogued as rs768942318, COSV50528601; called by muse, mutect2, varscan2
- MST1R | c.3105C>T p.V1035= | Silent (SNP) | VAF 108/341 reads (32%) | called by muse, mutect2, varscan2
- MYLK2 | c.114C>T p.P38= | Silent (SNP) | VAF 171/516 reads (33%) | catalogued as rs772195303; called by muse, mutect2, varscan2
- MYRF | c.471C>T p.L157= (on ENST00000278836 / NM_001127392.3; = p.L148= on NM_013279.4) | Silent (SNP) | VAF 135/437 reads (31%) | called by muse, mutect2, varscan2
- NAALAD2 | c.1447C>T p.L483= | Silent (SNP) | VAF 140/284 reads (49%) | catalogued as COSV58965905; called by muse, mutect2, varscan2
- NAB2 | c.1008C>T p.L336= | Silent (SNP) | VAF 554/678 reads (82%) | called by muse, mutect2, varscan2
- NCAM2 | c.1512C>T p.I504= | Silent (SNP) | VAF 35/185 reads (19%) | catalogued as COSV53091066; called by muse, mutect2, varscan2
- NFATC2 | c.183C>T p.P61= | Silent (SNP) | VAF 402/618 reads (65%) | catalogued as rs760704113, COSV65358809; called by muse, mutect2, varscan2
- NLRP11 | c.312C>T p.F104= | Silent (SNP) | VAF 84/161 reads (52%) | catalogued as COSV64088401; called by muse, mutect2, varscan2
- NLRP3 | c.564C>T p.I188= | Silent (SNP) | VAF 158/420 reads (38%) | catalogued as rs147631017; called by muse, mutect2, varscan2
- NOC2L | c.852C>T p.F284= | Silent (SNP) | VAF 420/479 reads (88%) | catalogued as rs756485369, COSV58989740; called by muse, mutect2, varscan2
- NOS1 | c.1068A>G p.K356= | Silent (SNP) | VAF 288/379 reads (76%) | called by muse, mutect2, varscan2
- NOTCH2 | c.6057G>A p.R2019= | Silent (SNP) | VAF 191/212 reads (90%) | called by muse, mutect2, varscan2
- NPAS1 | c.1602G>A p.R534= | Silent (SNP) | VAF 324/577 reads (56%) | catalogued as rs747248302; called by muse, mutect2, varscan2
- NPC1L1 | c.2010C>T p.L670= | Silent (SNP) | VAF 146/567 reads (26%) | catalogued as rs770902496; called by muse, mutect2, varscan2
- NPLOC4 | c.1239G>A p.K413= | Silent (SNP) | VAF 257/518 reads (50%) | catalogued as rs1397615642; called by muse, mutect2, varscan2
- NTRK2 | c.843C>T p.L281= | Silent (SNP) | VAF 334/357 reads (94%) | called by muse, mutect2, varscan2
- OR10A7 | c.267G>A p.R89= | Silent (SNP) | VAF 336/474 reads (71%) | catalogued as rs371021969; called by muse, mutect2, varscan2
- OR10C1 | c.417C>T p.H139= (on ENST00000622521; = p.H137= on NM_013941.3) | Silent (SNP) | VAF 578/811 reads (71%) | catalogued as rs763072767, COSV65824022; called by muse, mutect2, varscan2
- OR13C2 | c.699G>A p.G233= | Silent (SNP) | VAF 164/278 reads (59%) | called by muse, mutect2, varscan2
- OR2G6 | c.837C>T p.T279= | Silent (SNP) | VAF 181/338 reads (54%) | catalogued as COSV100598035; called by muse, mutect2, varscan2
- OR2H2 | c.636C>T p.I212= | Silent (SNP) | VAF 413/596 reads (69%) | catalogued as rs752919216; called by muse, mutect2, varscan2
- OR2I1P | c.81C>T p.F27= | Silent (SNP) | VAF 301/447 reads (67%) | called by muse, mutect2, varscan2
- OR2T4 | c.906G>A p.K302= | Silent (SNP) | VAF 215/628 reads (34%) | called by muse, mutect2
- OR4Q2 | c.664C>T p.L222= | Silent (SNP) | VAF 161/261 reads (62%) | catalogued as rs1053804627; called by muse, mutect2, varscan2
- OR51T1 | c.435G>A p.V145= | Silent (SNP) | VAF 166/371 reads (45%) | catalogued as COSV59025838; called by muse, varscan2
- OR6B1 | c.252T>C p.S84= | Silent (SNP) | VAF 180/546 reads (33%) | catalogued as rs1244797216; called by muse, mutect2, varscan2
- OR6C76 | c.330C>T p.F110= | Silent (SNP) | VAF 184/268 reads (69%) | catalogued as COSV60389177; called by muse, mutect2, varscan2
- OR6N2 | c.802C>T p.L268= | Silent (SNP) | VAF 152/320 reads (48%) | catalogued as rs1234107958, COSV59412913, COSV59413345; called by muse, mutect2, varscan2
- OR8A1 | c.585G>A p.E195= | Silent (SNP) | VAF 126/329 reads (38%) | catalogued as rs1272594991, COSV99420571; called by muse, mutect2, varscan2
- OR9K2 | c.771G>A p.E257= (on ENST00000305377; = p.E235= on NM_001005243.1) | Silent (SNP) | VAF 214/306 reads (70%) | catalogued as rs1405711113, COSV59532570; called by muse, mutect2, varscan2
- OSBPL2 | c.1146C>T p.F382= (on ENST00000313733 / NM_144498.4; = p.F370= on NM_014835.4) | Silent (SNP) | VAF 88/406 reads (22%) | catalogued as rs759094013; called by muse, mutect2, varscan2
- OTOP3 | c.1350C>T p.I450= | Silent (SNP) | VAF 433/690 reads (63%) | catalogued as rs751996365, COSV100172777; called by muse, mutect2, varscan2
- P2RX3 | c.129C>T p.F43= | Silent (SNP) | VAF 86/282 reads (30%) | called by muse, mutect2, varscan2
- PANX3 | c.471C>T p.L157= | Silent (SNP) | VAF 232/475 reads (49%) | catalogued as rs992944475, COSV52513429; called by muse, mutect2, varscan2
- PAQR6 | c.309C>T p.T103= | Silent (SNP) | VAF 372/746 reads (50%) | catalogued as rs1211032793, COSV52745310; called by muse, mutect2, varscan2
- PAX1 | c.489G>A p.G163= | Silent (SNP) | VAF 83/347 reads (24%) | called by muse, mutect2, varscan2
- PCDHA10 | c.1389G>A p.V463= | Silent (SNP) | VAF 136/597 reads (23%) | catalogued as rs1554150030; called by muse, mutect2
- PCDHA3 | c.1284G>A p.R428= | Silent (SNP) | VAF 78/283 reads (28%) | catalogued as rs782571599, COSV63538565; called by muse, mutect2, varscan2
- PCDHB1 | c.2073G>A p.L691= | Silent (SNP) | VAF 68/267 reads (25%) | catalogued as COSV60632291; called by muse, mutect2, varscan2
- PCDHB8 | c.1545C>T p.F515= | Silent (SNP) | VAF 257/1403 reads (18%) | catalogued as rs782426664, COSV50787337; called by muse, varscan2
- PCDHGA12 | c.43C>T p.L15= | Silent (SNP) | VAF 99/179 reads (55%) | called by muse, mutect2, varscan2
- PCDHGB2 | c.1527G>C p.A509= | Silent (SNP) | VAF 104/438 reads (24%) | called by muse, mutect2, varscan2
- PCK1 | c.1327C>T p.L443= | Silent (SNP) | VAF 251/383 reads (66%) | called by muse, mutect2, varscan2
- PEG3 | c.603G>A p.A201= | Silent (SNP) | VAF 138/248 reads (56%) | catalogued as rs759512604, COSV55639049; called by muse, mutect2, varscan2
- PER1 | c.2394C>T p.F798= | Silent (SNP) | VAF 395/723 reads (55%) | catalogued as rs1448260985; called by muse, mutect2, varscan2
- PFKFB4 | c.642C>T p.S214= | Silent (SNP) | VAF 109/302 reads (36%) | catalogued as rs1318369424; called by muse, mutect2, varscan2
- PIEZO2 | c.3759C>A p.I1253= | Silent (SNP) | VAF 82/451 reads (18%) | called by muse, mutect2, varscan2
- PIP5K1B | c.1257C>T p.A419= | Silent (SNP) | VAF 256/305 reads (84%) | called by muse, mutect2, varscan2
- PITPNM3 | c.765C>T p.G255= | Silent (SNP) | VAF 135/365 reads (37%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.4575G>A p.E1525= | Silent (SNP) | VAF 129/294 reads (44%) | catalogued as COSV101005690; called by muse, mutect2, varscan2
- PLCE1 | c.3318C>T p.T1106= | Silent (SNP) | VAF 73/339 reads (22%) | called by muse, mutect2, varscan2
- PLEKHD1 | c.990C>T p.S330= | Silent (SNP) | VAF 415/543 reads (76%) | catalogued as COSV59447574; called by muse, mutect2, varscan2
- PLVAP | c.861C>T p.A287= | Silent (SNP) | VAF 226/386 reads (59%) | called by muse, mutect2, varscan2
- PNPLA1 | c.936G>A p.K312= (on ENST00000394571 / NM_001374623.1; = p.K217= on NM_173676.2) | Silent (SNP) | VAF 88/453 reads (19%) | catalogued as COSV57237672; called by muse, mutect2, varscan2
- POTEB3 | c.96C>T p.F32= | Silent (SNP) | VAF 284/1742 reads (16%) | catalogued as rs1199742904; called by muse, mutect2
- POU3F2 | c.930G>A p.R310= | Silent (SNP) | VAF 101/401 reads (25%) | called by muse, mutect2, varscan2
- PPBP | c.138G>A p.A46= | Silent (SNP) | VAF 130/159 reads (82%) | catalogued as rs747703873, COSV56019765; called by muse, mutect2, varscan2
- PPFIBP2 | c.2385G>A p.E795= | Silent (SNP) | VAF 136/320 reads (43%) | catalogued as rs1381626338; called by muse, mutect2, varscan2
- PPP1R3A | c.3057G>A p.E1019= | Silent (SNP) | VAF 163/535 reads (30%) | catalogued as COSV52879434; called by muse, mutect2, varscan2
- PRAG1 | c.3579C>T p.S1193= | Silent (SNP) | VAF 234/364 reads (64%) | called by muse, mutect2, varscan2
- PRDM9 | c.1833G>A p.R611= | Silent (SNP) | VAF 211/776 reads (27%) | called by muse, mutect2, varscan2
- PRR23B | c.93G>A p.L31= | Silent (SNP) | VAF 329/544 reads (60%) | catalogued as rs781009963; called by muse, mutect2, varscan2
- PRSS55 | c.933G>A p.R311= | Silent (SNP) | VAF 250/391 reads (64%) | called by muse, mutect2, varscan2
- PSMD2 | c.447G>A p.E149= | Silent (SNP) | VAF 102/181 reads (56%) | called by muse, mutect2, varscan2
- PSTPIP1 | c.228C>T p.S76= | Silent (SNP) | VAF 83/480 reads (17%) | catalogued as COSV51200281; called by muse, mutect2, varscan2
- PTPRH | c.1848G>A p.A616= | Silent (SNP) | VAF 198/329 reads (60%) | catalogued as rs561329758, COSV54743004; called by muse, mutect2, varscan2
- PTX4 | c.621G>A p.Q207= (on ENST00000447419 / NM_001328608.2; = p.Q202= on NM_001013658.1) | Silent (SNP) | VAF 103/647 reads (16%) | called by muse, mutect2, varscan2
- PXMP2 | c.252G>A p.G84= | Silent (SNP) | VAF 158/184 reads (86%) | called by muse, mutect2, varscan2
- PYHIN1 | c.321G>A p.T107= | Silent (SNP) | VAF 161/309 reads (52%) | catalogued as COSV100932398; called by muse, mutect2, varscan2
- QRFPR | c.82C>T p.L28= | Silent (SNP) | VAF 314/612 reads (51%) | called by muse, mutect2, varscan2
130 further variants in this file (0 protein-altering or splice-affecting, 94 silent, 36 other) are not listed here.
